Gene-level copy-number profile of tumor specimen C3L-09985-02 from CPTAC case C3L-09985, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.2 years (26,008 days).
Specimen C3L-09985-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 05df7a1f-068f-4d16-8fb9-1f6067f3c876.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-09985-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/2f5265e7-51e5-4f22-b10d-9b896886fde6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 30; copy number 1: 101; copy number 2: 30,701; copy number 3: 18,197; copy number 4: 5,201; copy number 5: 2,084; copy number 6: 851; copy number 7: 922; copy number 8: 52; copy number 9: 7; copy number 10: 23; copy number 11: 32; copy number 12: 52; copy number 13: 13; copy number 21: 10; copy number 22: 43; copy number 23: 50; copy number 26: 13; copy number 43: 6.

Homozygous deletions (total copy number 0; autosomes only): 30 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr9:1,977,784–2,229,241, 5 genes: AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P.
- chr9:3,526,723–3,691,814, 3 genes: RFX3-AS1, AL354977.2, AL354977.1.
- chr9:3,875,584–3,901,248, 2 genes (within-gene range 0–2): AL137071.1, GLIS3-AS1.
- chr9:15,464,066–15,544,294, 5 genes (within-gene range 0–2): PSIP1, AL513423.1, RN7SL98P, FTH1P12, RNU6-246P.
- chr9:30,388,935–30,575,012, 2 genes: LINC01242, SLC4A1APP1.
- chr13:82,778,208–83,145,903, 3 genes: AL445255.1, GYG1P2, AL512782.1.
- chr22:21,354,563–21,379,701, 3 genes: LINC01651, AP000552.1, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,157 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–71,585, 9 genes, copy number 6: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5.
- chr1:266,855–827,796, 22 genes, copy number 6 (within-gene range 2–6): AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AL669831.3, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12, WBP1LP6, OR4F16, CICP3.
- chr1:143,419,625–144,265,326, 34 genes, copy number 6: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529.
- chr2:116,818,086–116,818,761, 1 gene, copy number 5: AC062016.2.
- chr4:46,734,827–48,426,201, 23 genes, copy number 5: COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2.
- chr7:14,145,049–14,974,777, 1 gene, copy number 5 (within-gene range 4–5): DGKB.
- chr7:14,814,131–23,532,041, 118 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,494 genes, copy number 5–8 (broad region; genes not listed).
- chr9:39,016,969–39,508,885, 13 genes, copy number 22: VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1, RN7SL640P, SPATA31A1, BX005214.3, FAM74A1, BX005214.1, BX005214.2, ZNF658B, SKP1P3.
- chr9:41,644,438–60,964,196, 49 genes, copy number 13–23: AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1, CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P, CR848007.2, SNX18P5, CYP4F60P, CR848007.1, CNN2P4, AL591441.1, FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:61,854,148–62,096,920, 1 gene, copy number 10 (within-gene range 4–10): FAM27C.
- chr9:61,944,232–63,143,401, 38 genes, copy number 10–12: CR769775.1, AL590399.4, AL590399.3, AL590399.6, SNORA70, RN7SL544P, AL590399.1, FGF7P6, AL590399.5, AL590399.2, BX664725.1, LINC01189, FGF7P7, BX005266.2, BX005266.1, CNTNAP3P5, RBPJP7, RAB28P2, BX005266.3, ATP5F1AP7, SDR42E1P3, FKBP4P7, LINC01410, AL512625.3, RNA5SP283, AL512625.2, PTGER4P2, CDK2AP2P2, LERFS, MYO5BP2, ADGRF5P1, FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4.
- chr9:64,369,394–64,637,586, 10 genes, copy number 21: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2.
- chr11:55,602,360–55,666,195, 4 genes, copy number 5: OR4C11, OR4P4, OR4S2, OR4C6.
- chr12:66,767–34,249,958, 831 genes, copy number 5 (broad region; genes not listed).
- chr15:34,489,002–34,521,791, 3 genes, copy number 5: HNRNPLP2, FSCN1P1, DNM1P5.
- chr16:1,972,053–2,089,491, 12 genes, copy number 12 (within-gene range 3–12): TBL3, NOXO1, GFER, AC005606.2, SYNGR3, AC005606.1, ZNF598, NPW, RN7SL219P, SLC9A3R2, NTHL1, TSC2.
- chr16:11,196,177–11,798,275, 24 genes, copy number 12: AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3, LITAF, SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1.
- chr16:15,790,975–15,932,294, 5 genes, copy number 11: AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20.
- chr16:16,317,444–16,350,590, 1 gene, copy number 9 (within-gene range 3–9): AC138969.1.
- chr16:16,329,305–16,398,594, 6 genes, copy number 9 (within-gene range 3–9): MIR6770-2, AC138969.3, PKD1P2, MIR6511A3, NPIPA7, AC136619.1.
- chr16:23,167,577–23,574,389, 15 genes, copy number 11: AC099482.2, SCNN1G, AC099482.1, SCNN1B, COG7, RN7SKP23, SNORA75, AC008915.1, AC008915.2, GGA2, CCNYL7, EARS2, SUB1P4, UBFD1, AC008870.2.
- chr16:27,550,133–28,211,965, 12 genes, copy number 11: KATNIP, AC002551.1, AC016597.1, AC016597.2, Y_RNA, GSG1L, RNU6-159P, RNU6-1241P, XPO6, TPRKBP2, AC136611.1, RNY1P10.
- chr17:28,648,346–30,895,869, 128 genes, copy number 5 (broad region; genes not listed).
- chr17:37,375,985–42,181,142, 255 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr18:21,871,446–23,026,488, 26 genes, copy number 22–26: AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:24,932,771–26,438,041, 20 genes, copy number 23–43: LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543.
- chr18:26,655,737–27,190,698, 1 gene, copy number 22 (within-gene range 2–22): AQP4-AS1.
- chr18:26,822,341–28,177,946, 16 genes, copy number 22: AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, CDH2, AC110015.1, AC006249.1.
- chr20:22,220,554–64,327,972, 985 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
